Somatic mutation profile of tumor specimen TCGA-IH-A3EA-01A (aliquot TCGA-IH-A3EA-01A-11D-A20D-08) from TCGA case TCGA-IH-A3EA, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 62.2 years (22,718 days).
Specimen TCGA-IH-A3EA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04542754-2042-46aa-a268-257103335245.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IH-A3EA-10A (Blood Derived Normal), aliquot TCGA-IH-A3EA-10A-01D-A20D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6dad36a-24f2-4da1-a19d-3669a3a6846d

The open-access MAF lists 1,778 somatic variants for this specimen: 1,196 protein-altering or splice-affecting, 528 silent, 54 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,085, Silent 528, Nonsense Mutation 80, Intron 20, RNA 18, Splice Region 17, Splice Site 7, 3'Flank 6, 5'Flank 5, Frame Shift Del 4, 5'UTR 3, 3'UTR 2.

Variants (750 of 1,778; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID2 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 24/84 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1424958105, COSV57595631, COSV57607050; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/137 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 82/136 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BVES | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 6/73 reads (8%) | catalogued as rs796206315, COSV58947369; ClinVar: pathogenic; called by muse, mutect2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 22/84 reads (26%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- INMT | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 18/50 reads (36%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.121); catalogued as rs759141767, COSV50000201; called by muse, mutect2, varscan2
- KCNJ8 | c.1250G>A p.G417E | Missense Mutation (SNP) | VAF 55/160 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.131); catalogued as COSV53715303; called by muse, mutect2, varscan2
- MYBPC3 | c.1483C>T p.R495W | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs397515905, CM081702, CM092562, COSV99921153; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TFAP2B | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 85/215 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs80338915, CM014603, COSV53831861; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADACL2 | c.93G>A p.W31* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as COSV62929669; called by muse, mutect2, varscan2
- ABCA12 | c.5993C>T p.S1998F (on ENST00000272895 / NM_173076.3; = p.S1680F on NM_015657.3) | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55969798; called by muse, mutect2, varscan2
- ABCA13 | c.8980C>T p.P2994S | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.093); catalogued as COSV101447284; called by muse, mutect2, varscan2
- ABCA13 | c.8981C>T p.P2994L | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as rs759857903, COSV71282609; called by muse, mutect2, varscan2
- ABCB1 | c.2936C>T p.S979L | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV55964752; called by muse, mutect2, varscan2
- ABCB5 | c.2432C>T p.S811F (on ENST00000404938 / NM_001163941.2; = p.S366F on NM_178559.6) | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.747); catalogued as rs1409477884, COSV51722060; called by muse, mutect2
- ABCC6 | c.2099C>A p.A700D | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV52748183; called by muse, mutect2, varscan2
- ABCG8 | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.92); PolyPhen benign (0.028); catalogued as rs762135880, COSV55390723; called by muse, mutect2, varscan2
- ABL2 | c.2072C>T p.S691F (on ENST00000502732 / NM_007314.4; = p.S676F on NM_005158.5) | Missense Mutation (SNP) | VAF 74/179 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.085); catalogued as COSV61021030; called by muse, mutect2, varscan2
- ABLIM3 | c.1228C>T p.P410S | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.334); catalogued as rs868073799, COSV100448349, COSV58649131; called by muse, mutect2
- ACAN | c.4877C>T p.P1626L | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs753824539, COSV61370296; called by muse, mutect2, varscan2
- ACAP3 | c.1700C>T p.S567F | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as COSV57644784; called by muse, mutect2, varscan2
- ACP4 | c.409A>T p.R137W | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV54518947; called by muse, mutect2, varscan2
- ACSM4 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV68069632; called by muse, mutect2, varscan2
- ACSS3 | c.1061G>A p.G354E | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV54102308; called by muse, mutect2, varscan2
- ACSS3 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.315); catalogued as COSV54102316; called by muse, mutect2, varscan2
- ACTN2 | c.1996C>T p.Q666* | Nonsense Mutation (SNP) | VAF 38/129 reads (29%) | catalogued as COSV63978541; called by muse, mutect2, varscan2
- ACTR1A | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 62/182 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV64024317; called by muse, mutect2, varscan2
- ADAM21 | c.304C>G p.Q102E | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV50812163; called by muse, mutect2, varscan2
- ADAMTS10 | c.1655C>T p.P552L | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as rs1216168299, COSV54359131, COSV99547550; called by muse, mutect2, varscan2
- ADAMTS10 | c.1654C>T p.P552S | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as COSV54355342; called by muse, mutect2, varscan2
- ADAMTS14 | c.525G>A p.A175= | Splice Region (SNP) | VAF 49/138 reads (36%) | catalogued as rs376839956; called by muse, mutect2, varscan2
- ADAMTS18 | c.2581C>T p.P861S | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.461); catalogued as rs866658923, COSV51401674; called by muse, mutect2, varscan2
- ADAMTS18 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1444092938, COSV51423671; called by muse, mutect2, varscan2
- ADAMTS20 | c.1445G>A p.R482Q | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs191978295, COSV67134703; called by muse, mutect2, varscan2
- ADAMTSL3 | c.823C>G p.Q275E | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV54448370, COSV54472214; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4505G>A p.G1502E | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV54447067; called by muse, mutect2, varscan2
- ADCY8 | c.2995G>A p.E999K | Missense Mutation (SNP) | VAF 112/150 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53929929; called by muse, mutect2, varscan2
- ADCY8 | c.1568G>A p.R523K | Missense Mutation (SNP) | VAF 184/248 reads (74%) | SIFT tolerated (0.05); PolyPhen benign (0.15); catalogued as rs772595688, COSV53929947, COSV99654758; called by muse, mutect2, varscan2
- ADCYAP1 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52486123; called by muse, mutect2
- ADD2 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as COSV52462126; called by muse, mutect2, varscan2
- ADGRB1 | c.3116C>T p.A1039V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as rs953941586, COSV60103800; called by muse, mutect2, varscan2
- ADGRG4 | c.9083G>A p.G3028E | Missense Mutation (SNP) | VAF 45/61 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs371979123, COSV54950602; called by muse, mutect2, varscan2
- ADGRG6 | c.2689C>T p.P897S | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51597613; called by muse, mutect2, varscan2
- ADGRL4 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.068); catalogued as COSV66066497; called by muse, mutect2, varscan2
- ADGRV1 | c.7407G>A p.W2469* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as COSV67996328; called by muse, mutect2, varscan2
- ADGRV1 | c.7588G>A p.D2530N | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.776); catalogued as COSV67996330; called by muse, varscan2
- ADGRV1 | c.7644G>A p.M2548I | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as COSV67988752; called by muse, varscan2
- ADGRV1 | c.14122G>A p.G4708R | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as COSV67996334; called by muse, mutect2, varscan2
- ADH1A | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as rs867643076, COSV52926317; called by muse, mutect2, varscan2
- ADH1B | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 77/246 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59295195; called by muse, mutect2, varscan2
- ADNP2 | c.2341G>T p.D781Y | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV51542709; called by muse, mutect2, varscan2
- ADORA2B | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.412); catalogued as rs1021224191, COSV58483714; called by muse, mutect2, varscan2
- AFF1 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57124911; called by muse, mutect2, varscan2
- AFF1 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 79/209 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as COSV100321001; called by muse, mutect2, varscan2
- AFMID | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59977765; called by muse, mutect2, varscan2
- AGO1 | c.1369C>T p.Q457* | Nonsense Mutation (SNP) | VAF 18/57 reads (32%) | catalogued as COSV64596634; called by muse, mutect2, varscan2
- AGO4 | c.2233C>T p.P745S | Missense Mutation (SNP) | VAF 78/179 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV64618877; called by muse, mutect2, varscan2
- AHNAK | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV57203821, COSV99948282; called by muse, mutect2, varscan2
- AHSG | c.910C>T p.P304S | Missense Mutation (SNP) | VAF 74/222 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.362); catalogued as rs1478596998, COSV56609528; called by muse, mutect2, varscan2
- AJAP1 | c.220G>A p.V74I | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV65448688, COSV65455055; called by muse, mutect2, varscan2
- AKAP11 | c.1043C>A p.S348* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV50303624; called by muse, mutect2, varscan2
- AKAP6 | c.6737C>T p.P2246L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.024); catalogued as COSV55234984; called by muse, mutect2, varscan2
- AKAP9 | c.8963C>T p.P2988L (on ENST00000359028; = p.P2964L on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.862); catalogued as COSV62358879; called by muse, mutect2, varscan2
- ALB | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.042); catalogued as rs768525028, COSV55743072; called by muse, mutect2, varscan2
- ALDH3A1 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56737101; called by muse, mutect2, varscan2
- ALK | c.1801C>T p.L601F | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0.029); catalogued as COSV66591309; called by muse, mutect2, varscan2
- ALPK2 | c.1784C>T p.S595F | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV64493298; called by muse, mutect2, varscan2
- ALS2 | c.3465G>A p.W1155* | Nonsense Mutation (SNP) | VAF 35/97 reads (36%) | catalogued as COSV51893152; called by muse, mutect2, varscan2
- ANK3 | c.8477C>T p.S2826F | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.191); catalogued as COSV55084339; called by muse, mutect2, varscan2
- ANK3 | c.3821C>T p.S1274F (on ENST00000280772 / NM_001320874.2; = p.S408F on NM_001149.3) | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55053591; called by muse, mutect2, varscan2
- ANKRD11 | c.4634C>T p.P1545L | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV56373074; called by muse, mutect2, varscan2
- ANKRD29 | c.855T>A p.N285K | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.162); catalogued as COSV52427987; called by muse, mutect2, varscan2
- ANKRD35 | c.1940C>T p.S647F | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as COSV62911401; called by muse, mutect2, varscan2
- ANKS1B | c.216G>A p.K72= | Splice Region (SNP) | VAF 20/49 reads (41%) | catalogued as COSV61378674; called by muse, mutect2, varscan2
- ANO4 | c.352C>T p.R118* (on ENST00000392977 / NM_001286615.2; = p.R83* on NM_178826.4) | Nonsense Mutation (SNP) | VAF 65/147 reads (44%) | catalogued as COSV54615264; called by muse, mutect2, varscan2
- ANO4 | c.508G>A p.E170K (on ENST00000392977 / NM_001286615.2; = p.E135K on NM_178826.4) | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV54615276; called by muse, mutect2, varscan2
- ANO9 | c.1984G>A p.D662N | Missense Mutation (SNP) | VAF 83/225 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.89); catalogued as COSV60385536; called by muse, mutect2, varscan2
- AOPEP | c.272C>G p.S91* | Nonsense Mutation (SNP) | VAF 32/67 reads (48%) | catalogued as COSV52924292, COSV99469412; called by muse, mutect2, varscan2
- AP2A2 | c.768G>C p.W256C | Missense Mutation (SNP) | VAF 64/235 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV59964470; called by muse, mutect2, varscan2
- AP2B1 | c.334T>A p.C112S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV52003835; called by muse, mutect2, varscan2
- APBB2 | c.1025C>T p.P342L (on ENST00000295974 / NM_001166050.2; = p.P343L on NM_004307.2) | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV55963670; called by muse, mutect2, varscan2
- APLF | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58149292; called by muse, mutect2, varscan2
- APOB | c.9469G>A p.G3157S | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51954669; called by muse, mutect2, varscan2
- APOB | c.5760G>A p.W1920* | Nonsense Mutation (SNP) | VAF 78/239 reads (33%) | catalogued as COSV51954681; called by muse, mutect2, varscan2
- APOBEC2 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 97/160 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753621134, COSV55143482, COSV55143714; called by muse, mutect2, varscan2
- APOL6 | c.754C>T p.L252F | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68749472; called by muse, mutect2, varscan2
- AQP3 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV53049162; called by muse, mutect2, varscan2
- ARHGAP11A | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.74); PolyPhen benign (0.009); catalogued as rs763168810, COSV64381710; called by muse, mutect2, varscan2
- ARHGEF11 | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 91/252 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63815863; called by muse, mutect2, varscan2
- ARID2 | c.2158C>T p.Q720* | Nonsense Mutation (SNP) | VAF 38/116 reads (33%) | catalogued as COSV57598698; called by muse, mutect2, varscan2
- ARL9 | c.463C>T p.R155W (on ENST00000640821 / NM_001363794.2; = p.R13W on NM_206919.2) | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777668617, COSV63991277, COSV63991652; called by muse, mutect2, varscan2
- ARMC4 | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as rs1327164758, COSV59475143; called by muse, mutect2, varscan2
- ARMC4 | c.1396C>T p.Q466* | Nonsense Mutation (SNP) | VAF 25/85 reads (29%) | catalogued as COSV59475161; called by muse, mutect2, varscan2
- ARPP21 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.338); catalogued as COSV51809301; called by muse, mutect2, varscan2
- ASGR2 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs748911594, COSV54690762, COSV54691996; called by muse, mutect2, varscan2
- ASTL | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.367); catalogued as COSV60905612; called by muse, mutect2, varscan2
- ASTN1 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56074994, COSV99920784; called by muse, mutect2, varscan2
- ASXL3 | c.884G>A p.G295E | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52480911; called by muse, mutect2, varscan2
- ASXL3 | c.6168A>C p.Q2056H | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); catalogued as COSV52480935; called by muse, mutect2, varscan2
- ATCAY | c.742G>C p.G248R | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.72); catalogued as COSV100008445, COSV56658323, COSV56659582; called by muse, mutect2, varscan2
- ATF1 | c.793C>T p.L265F | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV50394553, COSV50396200; called by muse, mutect2, varscan2
- ATG4A | c.569C>T p.P190L | Missense Mutation (SNP) | VAF 56/84 reads (67%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV58965898; called by muse, mutect2, varscan2
- ATP10B | c.2789G>A p.R930K | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs780232585, COSV59165674; called by muse, mutect2, varscan2
- ATP10B | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.996); catalogued as COSV58778373; called by muse, mutect2, varscan2
- ATP10D | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.158); catalogued as COSV56713661, COSV99905937; called by muse, mutect2, varscan2
- ATP13A5 | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.79); PolyPhen benign (0.05); catalogued as COSV60876083; called by mutect2, varscan2
- ATP7B | c.2380A>C p.K794Q | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV54444868; called by muse, mutect2, varscan2
- ATP8B4 | c.2320G>A p.D774N | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.579); catalogued as rs373435903; called by muse, mutect2, varscan2
- ATXN7 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV55757174; called by muse, mutect2, varscan2
- AVL9 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV59469712; called by muse, mutect2, varscan2
- AZGP1 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as COSV52799693; called by muse, mutect2, varscan2
- AZIN2 | c.105G>A p.T35= | Splice Region (SNP) | VAF 9/23 reads (39%) | catalogued as COSV53860970; called by muse, mutect2, varscan2
- B4GALT5 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV65495407; called by muse, mutect2, varscan2
- BAZ2A | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV51643731; called by muse, mutect2, varscan2
- BCAR1 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV50806506; called by muse, mutect2, varscan2
- BCL2L15 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV63643420; called by muse, mutect2, varscan2
- BCO2 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs754125457, COSV63065130; called by muse, mutect2, varscan2
- BEST3 | c.1350G>A p.W450* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as COSV58306129; called by muse, varscan2
- BEST3 | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.398); catalogued as COSV58301750; called by muse, varscan2
- BEX5 | c.280C>T p.L94F | Missense Mutation (SNP) | VAF 42/64 reads (66%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as COSV61329093; called by muse, mutect2, varscan2
- BIN2 | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.997); catalogued as COSV57208350; called by muse, mutect2, varscan2
- BLK | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs975732448, COSV52052840, COSV52056702; called by muse, mutect2, varscan2
- BLK | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV52056708; called by muse, mutect2, varscan2
- BMP5 | c.436C>T p.H146Y | Missense Mutation (SNP) | VAF 94/157 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as COSV63706898; called by muse, mutect2, varscan2
- BMP5 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 100/178 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868005204, COSV63701851, COSV63702549; called by muse, mutect2, varscan2
- BMPER | c.851G>A p.G284D | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV51832462; called by muse, mutect2, varscan2
- BNC2 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 104/299 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66158360; called by muse, mutect2, varscan2
- BOC | c.887C>T p.T296I | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.3); catalogued as rs1263338675, COSV56358579; called by muse, mutect2, varscan2
- BPIFB6 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.903); catalogued as COSV62755354; called by muse, mutect2, varscan2
- BRD3 | c.2098T>A p.S700T | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100325704; called by muse, mutect2, varscan2
- BSN | c.7465C>T p.P2489S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as COSV56528602; called by muse, mutect2, varscan2
- BTNL8 | c.911C>T p.S304F (on ENST00000340184 / NM_001040462.3; = p.F347= on NM_024850.2) | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99180607; called by muse, mutect2, varscan2
- BUB1 | c.183A>T p.K61N | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV57067548; called by muse, mutect2, varscan2
- C16orf54 | c.642G>A p.W214* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as COSV61477328; called by muse, mutect2, varscan2
- C19orf47 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV63509035; called by muse, mutect2, varscan2
- C1S | c.1921C>T p.P641S | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs782586920, COSV61070589; called by muse, mutect2, varscan2
- C1orf116 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as rs149585923; called by muse, mutect2, varscan2
- C2CD3 | c.2842C>T p.R948* | Nonsense Mutation (SNP) | VAF 23/78 reads (29%) | catalogued as rs1437215284, COSV58089808; called by muse, mutect2, varscan2
- C2orf16 | c.3949G>A p.E1317K | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as COSV62675812; called by muse, mutect2, varscan2
- C2orf78 | c.2620G>A p.E874K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68519521; called by muse, mutect2, varscan2
- C4orf17 | c.924G>A p.M308I | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV56745038; called by muse, mutect2, varscan2
- C5 | c.2791C>T p.P931S | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV56332498; called by muse, mutect2, varscan2
- C6 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV54710078; called by muse, mutect2, varscan2
- C7 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as COSV57481875; called by muse, mutect2, varscan2
- C7 | c.2158G>A p.E720K | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs761703740, COSV57473318; called by muse, mutect2, varscan2
- C8A | c.548G>A p.G183E | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63486674; called by muse, mutect2, varscan2
- C8orf34 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 81/106 reads (76%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV61398537; called by muse, mutect2, varscan2
- C9 | c.1566G>A p.M522I | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV54677939, COSV54682016; called by muse, mutect2, varscan2
- C9orf131 | c.608A>G p.H203R | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56614498; called by muse, mutect2, varscan2
- C9orf131 | c.2876G>A p.G959E | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as COSV56614511; called by muse, mutect2, varscan2
- CA10 | c.228G>A p.M76I | Missense Mutation (SNP) | VAF 87/263 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs267604958, COSV53362047, COSV53371994; called by muse, mutect2, varscan2
- CABIN1 | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 47/210 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs372879628; called by muse, varscan2
- CABP4 | c.671G>A p.G224E | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57800192; called by muse, mutect2, varscan2
- CACNA1A | c.2716G>A p.D906N | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as COSV64193210; called by muse, mutect2, varscan2
- CACNA1C | c.6080C>A p.P2027Q (on ENST00000399634 / NM_001167625.1; = p.P1956Q on NM_000719.7) | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as COSV59777245; called by muse, mutect2, varscan2
- CACNA1D | c.745C>T p.R249* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as COSV55466333; called by muse, mutect2, varscan2
- CACNA1D | c.5015G>A p.R1672Q (on ENST00000350061 / NM_001128840.3; = p.R1692Q on NM_000720.4) | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs148898845; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1E | c.3181G>A p.D1061N | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1558322481, COSV62429814; called by muse, mutect2, varscan2
- CACNA2D4 | c.1331G>A p.W444* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as COSV54950415; called by muse, mutect2, varscan2
- CALCR | c.746A>G p.N249S (on ENST00000649521 / NM_001164737.2; = p.N233S on NM_001742.4) | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV64012405; called by muse, mutect2, varscan2
- CAMK1G | c.410A>T p.N137I | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.264); catalogued as COSV50527348; called by muse, mutect2, varscan2
- CAMK4 | c.1124G>A p.G375E | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs867091227, COSV56667777, COSV99998868; called by muse, mutect2, varscan2
- CAMKV | c.1402G>A p.D468N | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV56558034; called by muse, mutect2, varscan2
- CAPN13 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV54428562; called by muse, mutect2, varscan2
- CAPN9 | c.463G>A p.D155N | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as COSV55240286; called by muse, mutect2, varscan2
- CARD11 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.718); catalogued as COSV67802414; called by muse, mutect2, varscan2
- CARD18 | c.262G>A p.G88S | Missense Mutation (SNP) | VAF 55/232 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV73233254; called by muse, mutect2, varscan2
- CARMIL1 | c.3391T>A p.S1131T | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.135); catalogued as rs868294655, COSV61524472; called by muse, mutect2, varscan2
- CASR | c.1475C>T p.P492L (on ENST00000490131; = p.P569L on NM_000388.4) | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as CM1310393, COSV56141800; called by muse, mutect2, varscan2
- CBLB | c.2153C>T p.S718F | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.054); catalogued as COSV51428712; called by muse, mutect2, varscan2
- CCDC102B | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 70/302 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as COSV60155480; called by muse, mutect2, varscan2
- CCDC105 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770472131, COSV52965159; called by muse, mutect2, varscan2
- CCDC144A | c.3607G>A p.E1203K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.116); catalogued as rs749777250, COSV60702252; called by muse, mutect2, varscan2
- CCDC59 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1322492170, COSV50262484; called by muse, mutect2, varscan2
- CCDC60 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as rs764208425, COSV59540294; called by muse, mutect2
- CCDC60 | c.926G>A p.R309K | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.99); catalogued as COSV59551349; called by muse, mutect2, varscan2
- CCDC7 | c.3761G>A p.R1254K | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated, low confidence (0.5); PolyPhen possibly damaging (0.702); catalogued as COSV56552778; called by muse, mutect2, varscan2
- CCKAR | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as rs763371054, COSV55164264; called by muse, mutect2, varscan2
- CCNJL | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as rs1215649927, COSV57445145, COSV57447286; called by muse, mutect2, varscan2
- CCR1 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as rs1189397328, COSV56122260; called by muse, mutect2, varscan2
- CCT8L2 | c.932G>A p.G311D | Missense Mutation (SNP) | VAF 69/375 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.614); catalogued as COSV63463932; called by muse, mutect2, varscan2
- CD163L1 | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as rs1352062997, COSV100550689, COSV58025518; called by muse, mutect2, varscan2
- CD163L1 | c.1708G>A p.D570N | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58025527; called by muse, mutect2, varscan2
- CD180 | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56519821; called by muse, mutect2, varscan2
- CD5 | c.1448C>T p.S483F | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57110189; called by muse, mutect2, varscan2
- CD6 | c.1226G>A p.G409E | Missense Mutation (SNP) | VAF 78/240 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57843111; called by muse, mutect2, varscan2
- CD6 | c.1949C>T p.P650L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.796); catalogued as COSV100532807, COSV100533342; called by muse, mutect2, varscan2
- CD84 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV60871097; called by muse, mutect2, varscan2
- CD8B | c.515C>T p.T172I | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV58928730; called by muse, mutect2, varscan2
- CDCP1 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as COSV56108330; called by muse, mutect2, varscan2
- CDH12 | c.2083C>T p.P695S | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.093); catalogued as COSV66432726, COSV66452282; called by muse, mutect2, varscan2
- CDH2 | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); catalogued as COSV52297833; called by muse, mutect2, varscan2
- CDH20 | c.2012G>A p.G671D | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53018887; called by muse, mutect2, varscan2
- CDH6 | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54074558; called by muse, mutect2, varscan2
- CDH7 | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 34/135 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs867768827, COSV59881646, COSV59895818; called by muse, mutect2, varscan2
- CDH9 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.491); catalogued as rs867901234, COSV50264302, COSV50324297; called by muse, mutect2, varscan2
- CDHR5 | c.2000G>A p.G667E (on ENST00000358353 / NM_001171968.2; = p.G673E on NM_021924.5) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100363919; called by muse, mutect2
- CDHR5 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs202157368, COSV51564015; called by muse, mutect2, varscan2
- CDK13 | c.2605C>T p.P869S | Missense Mutation (SNP) | VAF 118/419 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV51706984; called by muse, mutect2, varscan2
- CDKL3 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54745454; called by muse, mutect2, varscan2
- CDR1 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV65164124; called by muse, mutect2, varscan2
- CDSN | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.801); catalogued as COSV52540170, COSV52540242; called by muse, mutect2, varscan2
- CEACAM20 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV57603475; called by muse, mutect2, varscan2
- CES3 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.782); catalogued as rs563888639, COSV57595624; called by muse, mutect2, varscan2
- CFAP20 | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 72/202 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52631650; called by muse, mutect2, varscan2
- CFAP45 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs140567807; called by muse, mutect2, varscan2
- CFAP52 | c.1166T>A p.I389N | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV55349938; called by muse, mutect2, varscan2
- CFAP54 | c.4993C>T p.P1665S | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as COSV61571481; called by muse, mutect2, varscan2
- CFAP58 | c.382G>A p.V128M | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.146); catalogued as COSV100459172; called by muse, mutect2
- CFAP70 | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV60287312; called by muse, mutect2, varscan2
- CFHR1 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV57628063; called by muse, mutect2, varscan2
- CHD6 | c.1280A>G p.E427G | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.161); catalogued as COSV58562835; called by muse, mutect2, varscan2
- CHGB | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.677); catalogued as rs1404841467, COSV66761914; called by muse, mutect2, varscan2
- CHRDL2 | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.35); PolyPhen benign (0.103); catalogued as COSV55225499; called by muse, mutect2, varscan2
- CHSY3 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs777729488, COSV59272015; called by muse, mutect2, varscan2
- CILP2 | c.2063C>T p.T688I | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs965116854, COSV99365342; called by mutect2, varscan2
- CLCN5 | c.2084C>T p.P695L | Missense Mutation (SNP) | VAF 42/57 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56587043; called by muse, mutect2, varscan2
- CLK3 | c.721C>T p.R241W (on ENST00000395066 / NM_001130028.1; = p.R93W on NM_003992.4) | Missense Mutation (SNP) | VAF 78/213 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs760551120, COSV61415112; called by muse, mutect2, varscan2
- CLPX | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV55646976; called by muse, mutect2, varscan2
- CLSTN2 | c.2443C>T p.H815Y | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV71725495; called by muse, mutect2, varscan2
- CMYA5 | c.1211G>A p.G404E | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71408568; called by muse, mutect2, varscan2
- CNMD | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.817); catalogued as rs763428455, COSV65033492; called by muse, mutect2, varscan2
- CNOT1 | c.677T>C p.L226P | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV57781324; called by muse, mutect2, varscan2
- CNOT2 | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 41/137 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs755578360, COSV57507432; called by muse, mutect2, varscan2
- CNOT6L | c.99del p.K33Nfs*7 (on ENST00000504123 / NM_001286790.2; = p.K28Nfs*7 on NM_144571.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 68/204 reads (33%) | catalogued as COSV99361610; called by mutect2, pindel, varscan2
- CNTN2 | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.003); catalogued as COSV59353367; called by muse, mutect2, varscan2
- CNTN5 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1215380044, COSV54283284, COSV54294122; called by muse, mutect2, varscan2
- CNTN5 | c.2138C>T p.S713F | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54285848; called by muse, mutect2, varscan2
- CNTNAP4 | c.1604C>T p.S535F | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.149); catalogued as COSV56684168, COSV56697086; called by muse, mutect2, varscan2
- CNTRL | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53049156; called by muse, mutect2, varscan2
- COL14A1 | c.5096G>A p.G1699E | Missense Mutation (SNP) | VAF 35/46 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52870214; called by muse, mutect2, varscan2
- COL21A1 | c.2084G>A p.G695E | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769722166, COSV55163893, COSV99778638; called by muse, mutect2
- COL21A1 | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.866); catalogued as COSV55163346; called by muse, mutect2, varscan2
- COL4A2 | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64634991; called by muse, mutect2, varscan2
- COL4A3 | c.1172G>A p.R391K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.825); catalogued as COSV67420941; called by muse, mutect2, varscan2
- COL4A4 | c.3139C>T p.P1047S | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs776002982, COSV61637124; called by muse, mutect2, varscan2
- COL5A1 | c.859G>A p.G287R | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV65675582; called by muse, mutect2, varscan2
- COL6A3 | c.8568-1G>A p.X2856_splice | Splice Site (SNP) | VAF 28/74 reads (38%) | catalogued as COSV55112238; called by muse, mutect2, varscan2
- COL8A2 | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57443643; called by muse, mutect2
- COL9A1 | c.1577G>A p.G526E | Missense Mutation (SNP) | VAF 63/127 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57881370; called by muse, mutect2, varscan2
- COL9A1 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.725); catalogued as rs866458074, COSV57894236; called by muse, mutect2, varscan2
- COL9A2 | c.1817C>T p.P606L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as rs868108157; called by muse, mutect2
- COPA | c.3557C>T p.P1186L | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54106488; called by muse, mutect2, varscan2
- COPA | c.2823G>A p.R941= | Splice Region (SNP) | VAF 52/150 reads (35%) | catalogued as COSV54110174; called by muse, mutect2, varscan2
- CORO7 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs759601582, COSV52028817; called by muse, mutect2, varscan2
- CORO7 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV52034444; called by muse, mutect2
- CPN2 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1172984659, COSV60472226; called by muse, mutect2, varscan2
- CPSF6 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.981); catalogued as COSV57018722; called by muse, mutect2, varscan2
- CPZ | c.1882G>A p.D628N (on ENST00000360986 / NM_001014447.3; = p.D617N on NM_003652.3) | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs751803458, COSV59926477; called by muse, mutect2, varscan2
- CRACD | c.2783C>T p.S928F | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as COSV51732567; called by muse, mutect2, varscan2
- CRNKL1 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs1417028714, COSV55648979; called by muse, mutect2, varscan2
- CRYBG1 | c.2620C>T p.L874F | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.017); catalogued as COSV64814878; called by muse, mutect2, varscan2
- CRYBG1 | c.2848C>T p.P950S | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.652); catalogued as COSV64814881; called by muse, mutect2, varscan2
- CSF1 | c.1538G>A p.G513E | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60035651; called by muse, mutect2, varscan2
- CSMD1 | c.10400G>A p.R3467K (on ENST00000520002; = p.R3466K on NM_033225.6) | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV59390219; called by muse, mutect2, varscan2
- CSMD2 | c.6994G>A p.E2332K | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.403); catalogued as COSV53933880; called by muse, mutect2, varscan2
- CSN1S1 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 116/392 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV55892426; called by muse, mutect2, varscan2
- CSRP1 | c.29G>C p.C10S | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60638132; called by muse, mutect2, varscan2
- CTNND2 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as COSV58931572; called by muse, mutect2, varscan2
- CTSS | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 60/200 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV100935041, COSV64566055, COSV64567163; called by muse, mutect2, varscan2
- CUBN | c.2880G>A p.W960* | Nonsense Mutation (SNP) | VAF 47/148 reads (32%) | catalogued as COSV64728280; called by muse, mutect2, varscan2
- CUL9 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52735414; called by muse, mutect2, varscan2
- CWH43 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs751413481, COSV56936054; called by muse, mutect2, varscan2
- CXorf21 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 68/92 reads (74%) | SIFT tolerated (0.08); PolyPhen benign (0.192); catalogued as COSV66762624; called by muse, mutect2, varscan2
- CYP19A1 | c.599A>G p.N200S | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53062748; called by muse, mutect2, varscan2
- CYP2A13 | c.1322G>A p.G441E | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57840348; called by muse, mutect2, varscan2
- CYP2C19 | c.179T>G p.I60S | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as COSV64909639; called by muse, varscan2
- CYP2C19 | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64906876, COSV64907112; called by muse, varscan2
- CYP3A7 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1220927730, COSV60480780; called by muse, mutect2, varscan2
- CYP4A11 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT tolerated (0.71); PolyPhen benign (0.025); catalogued as rs144065752, COSV60225915; called by muse, mutect2, varscan2
- CYP4A22 | c.1265C>T p.P422L | Missense Mutation (SNP) | VAF 133/335 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.443); catalogued as COSV53742672; called by muse, mutect2, varscan2
- CYP4B1 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.53); PolyPhen benign (0.029); catalogued as COSV54722648; called by muse, mutect2, varscan2
- CYP4F12 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs750936191, COSV61176952; called by muse, mutect2, varscan2
- CYP4F12 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61176961; called by muse, mutect2, varscan2
- CYP4F2 | c.648G>A p.E216= | Splice Region (SNP) | VAF 48/131 reads (37%) | catalogued as COSV50000519; called by muse, mutect2, varscan2
- DAB1 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV59725348; called by muse, mutect2, varscan2
- DACH2 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as rs866178574, COSV64163143; called by muse, mutect2, varscan2
- DACT1 | c.721T>C p.F241L | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as rs1242841457, COSV60022245, COSV60023745; called by muse, mutect2, varscan2
- DBN1 | c.1658C>T p.S553F | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as rs1283359395, COSV52793572; called by muse, mutect2, varscan2
- DCC | c.4123C>T p.P1375S | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV71431455, COSV71441327; called by muse, mutect2, varscan2
- DDX4 | c.1617G>A p.G539= | Splice Region (SNP) | VAF 36/118 reads (31%) | catalogued as COSV61757609; called by muse, mutect2, varscan2
- DENND3 | c.187C>T p.H63Y | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52807420; called by muse, mutect2, varscan2
- DENND3 | c.2804C>G p.T935S | Missense Mutation (SNP) | VAF 86/120 reads (72%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV52807429, COSV99370382; called by muse, mutect2, varscan2
- DEUP1 | c.1200G>A p.M400I | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV53217197; called by muse, mutect2, varscan2
- DGCR2 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 362/645 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54222724; called by muse, mutect2, varscan2
- DGLUCY | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV56370602; called by muse, mutect2, varscan2
- DHX57 | c.215G>T p.R72L | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV54882222, COSV54891848; called by muse, mutect2, varscan2
- DIO3 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV63773803; called by muse, mutect2, varscan2
- DLEC1 | c.2848G>A p.E950K | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.79); catalogued as COSV57297655; called by muse, mutect2, varscan2
- DLGAP3 | c.2375C>T p.P792L | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as COSV52395210; called by muse, mutect2, varscan2
- DMBT1 | c.6365C>T p.P2122L (on ENST00000338354 / NM_001377530.1; = p.P1365L on NM_004406.3) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as COSV100354515; called by muse, mutect2, varscan2
- DNAH10 | c.2011G>A p.E671K (on ENST00000409039; = p.E610K on NM_207437.3) | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV69003083; called by muse, mutect2, varscan2
- DNAH2 | c.3658C>T p.L1220F | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.461); catalogued as COSV66723589; called by muse, mutect2, varscan2
- DNAH3 | c.9250C>T p.P3084S | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1227146188, COSV54555580; called by muse, mutect2, varscan2
- DNAH5 | c.12403C>T p.H4135Y | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as rs1420356971, COSV54255031; called by muse, mutect2, varscan2
- DNAH5 | c.7321C>T p.Q2441* | Nonsense Mutation (SNP) | VAF 26/70 reads (37%) | catalogued as COSV54255050; called by muse, mutect2, varscan2
- DNAH5 | c.5089G>A p.E1697K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54201305; called by muse, mutect2, varscan2
- DNAH5 | c.4951G>A p.E1651K | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54251553; called by muse, varscan2
- DNAH5 | c.2270C>T p.A757V | Missense Mutation (SNP) | VAF 75/193 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV54255093; called by muse, mutect2, varscan2
- DNAH5 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.011); catalogued as rs752339132, COSV54255104; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH7 | c.6736C>T p.H2246Y | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1361587243, COSV56751994; called by muse, mutect2, varscan2
- DNAH7 | c.4789G>A p.E1597K | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56788901; called by muse, mutect2, varscan2
- DNAH7 | c.2302C>T p.R768C | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs192646926; called by muse, mutect2, varscan2
- DNAH8 | c.7022C>T p.S2341F | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV59425853; called by muse, mutect2, varscan2
- DNM3 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62468114; called by muse, mutect2, varscan2
- DOCK2 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs756449193, COSV56940972; called by muse, mutect2, varscan2
- DPPA4 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as COSV59512646; called by muse, mutect2, varscan2
- DPYD | c.1817C>T p.S606F | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64616284; called by muse, mutect2, varscan2
- DPYD | c.345G>A p.M115I | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs377169736, COSV60078822, COSV60082730; called by muse, mutect2, varscan2
- DRD1 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.039); catalogued as COSV67105263; called by muse, mutect2, varscan2
- DRD5 | c.1064A>G p.N355S | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58578039; called by muse, mutect2, varscan2
- DSC3 | c.2285G>A p.G762D | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); catalogued as COSV64572936, COSV64575730; called by muse, mutect2, varscan2
- DSC3 | c.1181C>T p.T394I | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.566); catalogued as COSV64575735; called by muse, varscan2
- DSCAM | c.4970G>A p.R1657Q | Missense Mutation (SNP) | VAF 69/214 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.728); catalogued as rs766747740, COSV68037397; called by muse, mutect2, varscan2
- DSCAM | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.055); catalogued as COSV68037403; called by muse, mutect2, varscan2
- DSG1 | c.1166C>T p.S389L | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV57139704; called by muse, mutect2, varscan2
- DSG1 | c.2799G>A p.M933I | Missense Mutation (SNP) | VAF 215/382 reads (56%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV57139718; called by muse, mutect2, varscan2
- DSG3 | c.443T>C p.L148S | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57130024; called by muse, mutect2, varscan2
- DSP | c.5332G>A p.E1778K | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.086); catalogued as COSV65796443; called by muse, varscan2
- DSP | c.7870G>A p.D2624N | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs908955791, COSV65796448; called by muse, mutect2, varscan2
- DUSP4 | c.803C>T p.A268V | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs771553603, COSV53545720; called by muse, mutect2, varscan2
- DYNC2H1 | c.11644C>T p.P3882S | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62108080; called by muse, mutect2, varscan2
- E2F3 | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as COSV60900040; called by muse, mutect2, varscan2
- EBF2 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.184); catalogued as COSV68775882; called by muse, mutect2, varscan2
- ECI2 | c.280G>A p.D94N (on ENST00000380118 / NM_206836.3; = p.D64N on NM_006117.2) | Missense Mutation (SNP) | VAF 72/321 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.124); catalogued as COSV60989580; called by muse, mutect2, varscan2
- EDF1 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs1358420535, COSV56374915; called by muse, mutect2, varscan2
- EDNRB | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV57528505; called by muse, mutect2, varscan2
- EFCAB5 | c.3385G>A p.E1129K | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.012); catalogued as rs772820311, COSV57928171; called by muse, mutect2, varscan2
- EFHC2 | c.923G>A p.G308D | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as rs1301321956, COSV69554549; called by muse, mutect2, varscan2
- EIF2AK1 | c.808A>G p.K270E | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV52241523, COSV52243630; called by muse, mutect2, varscan2
- ELAC2 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 44/129 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV62034877; called by muse, mutect2, varscan2
- EMB | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.164); catalogued as COSV57484816; called by muse, mutect2, varscan2
- ENAM | c.157A>G p.K53E | Missense Mutation (SNP) | VAF 95/259 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121908109, CM020933, COSV68537121; called by muse, mutect2, varscan2
- ENAM | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68535210; called by muse, mutect2, varscan2
- ENAM | c.3239G>A p.S1080N | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV68537126; called by muse, mutect2, varscan2
- ENTPD5 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 72/192 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.961); catalogued as rs761661105, COSV58221517; called by muse, mutect2, varscan2
- EP400 | c.1687C>T p.P563S | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV57787727; called by muse, mutect2, varscan2
- EPB41L4B | c.2462C>T p.T821I | Missense Mutation (SNP) | VAF 51/170 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV65805249; called by muse, mutect2, varscan2
- EPG5 | c.6862C>T p.L2288F | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56353245; called by muse, mutect2, varscan2
- EPHA6 | c.2386A>T p.R796* (on ENST00000389672 / NM_001080448.3; = p.R188* on NM_173655.4) | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV67595488; called by muse, mutect2, varscan2
- EPPK1 | c.449G>A p.W150* | Nonsense Mutation (SNP) | VAF 31/37 reads (84%) | catalogued as COSV73262431; called by muse, mutect2, varscan2
- ERBB4 | c.2870G>A p.W957* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV61515331; called by muse, mutect2, varscan2
- EREG | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55262742; called by muse, mutect2, varscan2
- ERICH3 | c.3385G>A p.E1129K | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.209); catalogued as rs866558257, COSV58599808; called by muse, mutect2, varscan2
- ERICH3 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100443789, COSV58603045; called by muse, mutect2, varscan2
- ERICH3 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs866357333, COSV58619730; called by muse, mutect2, varscan2
- ERMAP | c.1163C>T p.S388F | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.944); catalogued as COSV60274944; called by muse, mutect2, varscan2
- ESR2 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50838806; called by muse, mutect2, varscan2
- ESRRG | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV63161188, COSV63176499; called by muse, mutect2, varscan2
- ESYT3 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56679808; called by muse, mutect2, varscan2
- ETS2 | c.1259G>A p.G420D | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62874578; called by muse, mutect2, varscan2
- ETV1 | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV54152304; called by muse, mutect2, varscan2
- EVX1 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56086086; called by muse, mutect2, varscan2
- EYA3 | c.1075G>T p.D359Y | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65817863; called by muse, mutect2, varscan2
- F10 | c.867G>A p.G289= | Splice Region (SNP) | VAF 98/233 reads (42%) | catalogued as rs546723477, COSV65023250; called by muse, mutect2, varscan2
- FAIM | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV58159686; called by muse, mutect2, varscan2
- FAM107B | c.139C>T p.P47S (on ENST00000378458 / NM_001320737.1; = p.P222S on NM_031453.3) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51686511, COSV51693713; called by muse, mutect2, varscan2
- FAM117B | c.1747C>T p.P583S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.053); catalogued as COSV57422662; called by muse, mutect2, varscan2
- FAM135B | c.2689C>T p.H897Y | Missense Mutation (SNP) | VAF 94/123 reads (76%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.086); catalogued as COSV52715103; called by muse, mutect2, varscan2
- FAM170A | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 64/92 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58927351; called by muse, mutect2, varscan2
- FAM171A1 | c.2476G>A p.G826S | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV65320542; called by muse, mutect2, varscan2
- FAM171B | c.2383C>T p.P795S | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.55); catalogued as COSV59009115; called by muse, mutect2, varscan2
- FAM71B | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV57230351; called by muse, mutect2, varscan2
- FAM83A | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 113/123 reads (92%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV52688509; called by muse, mutect2, varscan2
- FAM83B | c.1688C>T p.S563F | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100174467, COSV60927369; called by muse, mutect2, varscan2
- FAM83F | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.71); catalogued as rs373369149; called by muse, mutect2, varscan2
- FARS2 | c.1262T>A p.M421K | Missense Mutation (SNP) | VAF 120/194 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV51176646; called by muse, mutect2, varscan2
- FAT2 | c.5020C>T p.P1674S | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.248); catalogued as COSV55830400, COSV99943648; called by muse, mutect2, varscan2
- FAT4 | c.5678C>T p.P1893L | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV100630049, COSV58711166; called by muse, mutect2, varscan2
- FAT4 | c.6493G>A p.E2165K | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58685937; called by muse, mutect2, varscan2
- FAT4 | c.13955C>T p.S4652L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV58680974, COSV58701419; called by muse, mutect2, varscan2
- FBXO40 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV57528172; called by muse, mutect2, varscan2
- FBXW10 | c.1466G>A p.R489Q | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1410185429, COSV100111744, COSV57316985; called by muse, mutect2, varscan2
- FCGBP | c.5647C>T p.P1883S | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.108); catalogued as rs1266121313; called by muse, varscan2
- FCGR3B | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV54212454; called by muse, mutect2, varscan2
- FCRL4 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.377); catalogued as COSV54860901, COSV54862331; called by muse, mutect2, varscan2
- FCRL5 | c.1525C>T p.H509Y | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs865989930, COSV62512426, COSV62515233; called by muse, mutect2, varscan2
- FER1L6 | c.4505G>A p.G1502E | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as COSV67553020; called by muse, mutect2, varscan2
- FGFR4 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV52810504; called by muse, mutect2
- FHL5 | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV58740564, COSV58740620; called by muse, mutect2, varscan2
- FIBP | c.1010C>T p.S337F (on ENST00000338369 / NM_198897.2; = p.S330F on NM_004214.5) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.198); catalogued as COSV57173342; called by muse, mutect2, varscan2
- FLG | c.2968G>A p.E990K | Missense Mutation (SNP) | VAF 131/345 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.017); catalogued as rs764938074, COSV64241010; called by muse, mutect2, varscan2
- FLT4 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as rs757307082, COSV56123997; called by muse, mutect2, varscan2
- FOLH1 | c.961G>A p.G321R | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143707827, COSV57048119, COSV57054495; called by muse, mutect2, varscan2
- FOXP1 | c.1876C>T p.P626S | Missense Mutation (SNP) | VAF 101/293 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV59548256; called by muse, mutect2, varscan2
- FOXP2 | c.1525T>G p.Y509D | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63494670; called by muse, mutect2, varscan2
- FPR3 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as COSV59329921; called by muse, mutect2, varscan2
- FREM1 | c.5633C>T p.P1878L | Missense Mutation (SNP) | VAF 88/271 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs776747737, COSV66530910; called by muse, mutect2, varscan2
- FRMD8 | c.1064C>T p.S355F | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV58214432; called by muse, mutect2, varscan2
- FSD2 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58013406; called by muse, mutect2, varscan2
- FUCA1 | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV65699671; called by muse, mutect2, varscan2
- FUT3 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779363554, COSV54605204; called by muse, mutect2, varscan2
- FUT9 | c.235C>T p.L79F | Missense Mutation (SNP) | VAF 37/63 reads (59%) | SIFT tolerated (0.18); PolyPhen benign (0.282); catalogued as COSV56142731, COSV56157944; called by muse, mutect2, varscan2
- FYB2 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV58582867; called by muse, mutect2, varscan2
- GABPB2 | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 36/105 reads (34%) | catalogued as rs768860075, COSV64460664; called by muse, mutect2, varscan2
- GABRA6 | c.412A>T p.I138L | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.029); catalogued as COSV50881974, COSV50896316; called by muse, mutect2, varscan2
- GABRG1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT tolerated (1); PolyPhen possibly damaging (0.689); catalogued as COSV54951561, COSV54962652; called by muse, mutect2, varscan2
- GABRG2 | c.77G>A p.W26* | Nonsense Mutation (SNP) | VAF 9/54 reads (17%) | catalogued as COSV100729911, COSV62720874; called by muse, mutect2, varscan2
- GABRQ | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 138/201 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100941220, COSV64781520; called by muse, mutect2, varscan2
- GABRQ | c.1766C>T p.S589F | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as rs782375829, COSV64784115; called by muse, mutect2, varscan2
- GABRR1 | c.1304C>T p.S435F | Missense Mutation (SNP) | VAF 58/100 reads (58%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.516); catalogued as COSV65619450; called by muse, mutect2, varscan2
- GAD2 | c.674G>A p.R225K | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as COSV52169431; called by muse, mutect2, varscan2
- GAD2 | c.1745G>A p.G582E | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52169442; called by muse, mutect2, varscan2
- GALE | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1342042645, COSV65721112; called by muse, mutect2, varscan2
- GALNT6 | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 22/32 reads (69%) | catalogued as rs552999736, COSV62543451; called by muse, mutect2, varscan2
- GAP43 | c.143G>A p.R48K | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59348698; called by muse, mutect2, varscan2
- GAP43 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.028); catalogued as COSV59348714; called by muse, mutect2, varscan2
- GBA | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.46); catalogued as CM057094, CM077547, COSV100516509, COSV59171182; called by muse, mutect2, varscan2
- GC | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs771823776, COSV56735709; called by muse, mutect2, varscan2
- GCAT | c.990C>G p.F330L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50650480; called by muse, mutect2, varscan2
- GCN1 | c.7829C>T p.A2610V | Missense Mutation (SNP) | VAF 68/178 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as COSV56115392; called by muse, mutect2, varscan2
- GCOM1 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.391); catalogued as COSV51094507; called by muse, mutect2, varscan2
- GFRA3 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.922); catalogued as rs1346871812, COSV51228052; called by muse, mutect2, varscan2
- GIMAP2 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.086); catalogued as rs150902506, COSV56236470; called by muse, mutect2, varscan2
- GIMAP7 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1563302308, COSV57960869; called by muse, mutect2
- GIMAP8 | c.589G>A p.G197R | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs147231393, COSV56233045; called by muse, mutect2, varscan2
- GJA1 | c.803T>C p.F268S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV56999799; called by muse, mutect2, varscan2
- GLDC | c.1661C>T p.P554L | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1244239144, COSV100393769, COSV100394733; called by muse, mutect2, varscan2
- GLDC | c.1660C>T p.P554S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.798); catalogued as COSV100394734; called by muse, mutect2, varscan2
- GLI2 | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs202141899, CM1514050, COSV58052235; called by muse, mutect2, varscan2
- GLIPR1 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV56993138; called by muse, mutect2, varscan2
- GLIS3 | c.2063G>A p.R688K | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0.1); catalogued as rs1470189708, COSV60936822; called by muse, mutect2, varscan2
- GLRA2 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as COSV54336084, COSV54349118; called by muse, mutect2, varscan2
- GMPS | c.2017C>T p.P673S | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.104); catalogued as COSV55812251; called by muse, mutect2, varscan2
- GNL3 | c.98G>T p.R33I | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66921109; called by muse, mutect2, varscan2
- GOLGA2 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.111); catalogued as COSV70168936; called by muse, mutect2, varscan2
- GOT2 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55333624; called by muse, mutect2, varscan2
- GPR119 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 49/71 reads (69%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.67); catalogued as COSV52276702; called by muse, mutect2, varscan2
- GPR18 | c.180T>A p.Y60* | Nonsense Mutation (SNP) | VAF 19/78 reads (24%) | catalogued as COSV61621535; called by muse, mutect2, varscan2
- GPR19 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60124813; called by muse, mutect2, varscan2
- GPRC5D | c.532C>T p.L178F | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.105); catalogued as COSV57432391; called by muse, mutect2, varscan2
- GPRC6A | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.16); PolyPhen benign (0.268); catalogued as rs530814514, COSV59956243; called by muse, mutect2, varscan2
- GPRIN1 | c.1496C>T p.S499F | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs867504070, COSV56146025; called by muse, mutect2, varscan2
- GRHL1 | c.659G>A p.G220D | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.068); catalogued as rs1186441095, COSV61411143; called by muse, mutect2, varscan2
- GRIA1 | c.810G>A p.W270* | Nonsense Mutation (SNP) | VAF 45/123 reads (37%) | catalogued as COSV53603827; called by muse, mutect2, varscan2
- GRIA2 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.915); catalogued as COSV52400753, COSV52406562; called by muse, mutect2, varscan2
- GRID1 | c.1129C>T p.L377F | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60056209; called by muse, mutect2, varscan2
- GRID2 | c.1991C>T p.S664F | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs374167901, COSV56193082; called by muse, mutect2, varscan2
- GRIN2A | c.3199C>T p.R1067W | Missense Mutation (SNP) | VAF 71/96 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58021247; called by muse, mutect2, varscan2
- GRM7 | c.668C>T p.T223I | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1194497482, COSV63173865; called by muse, mutect2, varscan2
- GRM7 | c.1717C>T p.R573* | Nonsense Mutation (SNP) | VAF 41/130 reads (32%) | catalogued as rs267599933, COSV63130808; called by muse, mutect2, varscan2
- GSAP | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs193205180, COSV57530344; called by muse, mutect2, varscan2
- GTF3C1 | c.5746C>T p.L1916F | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.087); catalogued as COSV62245318; called by muse, mutect2, varscan2
- GTSE1 | c.1798C>T p.P600S | Missense Mutation (SNP) | VAF 71/136 reads (52%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.858); catalogued as COSV71888913; called by muse, mutect2, varscan2
- GUCY1A1 | c.1841G>A p.R614Q | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.789); catalogued as rs772453526, COSV56649256, COSV56653947; called by muse, mutect2, varscan2
- GUCY1A2 | c.2135C>T p.S712L | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.574); catalogued as rs1383258563, COSV56477773; called by muse, mutect2, varscan2
- GYPE | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV62262846; called by muse, mutect2, varscan2
- GZMK | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.167); catalogued as COSV50248911; called by muse, mutect2, varscan2
- HABP2 | c.1324C>T p.P442S | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.641); catalogued as COSV63491481; called by muse, mutect2, varscan2
- HAO1 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as rs375310753; called by muse, mutect2, varscan2
- HCFC2 | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as COSV99983379; called by muse, mutect2, varscan2
- HCFC2 | c.214T>G p.C72G | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV57560601; called by muse, mutect2, varscan2
- HDAC11 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV55472488; called by muse, mutect2, varscan2
- HEPH | c.2812G>A p.E938K (on ENST00000343002; = p.E671K on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.611); catalogued as COSV57958731; called by muse, mutect2, varscan2
- HERC4 | c.1295C>T p.S432F | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53271955; called by muse, mutect2, varscan2
- HEYL | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV65721809, COSV65722099; called by muse, mutect2, varscan2
- HGF | c.625+1G>A p.X209_splice | Splice Site (SNP) | VAF 23/77 reads (30%) | catalogued as COSV55957827; called by muse, mutect2, varscan2
- HGFAC | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV66977361; called by muse, mutect2, varscan2
- HIF3A | c.1334C>T p.S445L (on ENST00000377670 / NM_152795.4; = p.S376L on NM_022462.4) | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs141145645, COSV52195617; called by muse, mutect2, varscan2
- HINFP | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV63431783; called by muse, mutect2, varscan2
- HJURP | c.1765C>T p.Q589* | Nonsense Mutation (SNP) | VAF 23/77 reads (30%) | catalogued as COSV64979121; called by muse, mutect2, varscan2
- HK3 | c.1483G>A p.D495N | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV52845082; called by muse, mutect2, varscan2
- HMG20A | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs762710203, COSV60314409; called by muse, mutect2, varscan2
- HMOX2 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV54861920; called by muse, mutect2, varscan2
- HOOK2 | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.693); catalogued as COSV53404226; called by muse, mutect2, varscan2
- HOXB2 | c.968C>A p.S323Y | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV57487708, COSV57488379; called by muse, mutect2, varscan2
- HOXB2 | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57488387; called by muse, mutect2, varscan2
- HPS4 | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV61106051; called by muse, mutect2, varscan2
- HRH1 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 104/232 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200787735, COSV67955214; called by muse, mutect2, varscan2
- HS3ST6 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV99562927; called by muse, mutect2, varscan2
- HS6ST3 | c.905C>T p.T302I | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs868456363, COSV65019308; called by muse, mutect2, varscan2
- HTR3C | c.1103G>A p.G368E | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.023); catalogued as rs1203317364, COSV59174677; called by muse, mutect2, varscan2
- HUNK | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as COSV54234968; called by muse, mutect2, varscan2
- HYDIN | c.8357G>A p.R2786Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as rs1211165728, COSV99992604; called by muse, mutect2, varscan2
- ICA1 | c.676C>G p.L226V | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55584902, COSV55585182; called by muse, mutect2, varscan2
- IGHV3-21 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.165); catalogued as rs782419151; called by muse, mutect2, varscan2
- IGHV4-34 | c.218G>A p.W73* | Nonsense Mutation (SNP) | VAF 26/89 reads (29%) | catalogued as rs781110683; called by muse, varscan2
- IGSF9B | c.3673C>T p.R1225C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs767068283, COSV58068700, COSV58069177; called by muse, mutect2, varscan2
- IL5RA | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as rs376063854; called by muse, varscan2
- IL7R | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs867618621, COSV57405921, COSV57412932; called by muse, mutect2, varscan2
- INA | c.1201G>A p.E401K | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100878603, COSV63976676; called by muse, mutect2, varscan2
- INF2 | c.2135C>T p.P712L | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53030475; called by muse, mutect2, varscan2
- INTS5 | c.1897C>T p.P633S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.637); catalogued as COSV57953772; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.90G>A p.M30I | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as COSV67336627; called by muse, mutect2, varscan2
- IQSEC1 | c.2489C>T p.S830F | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV56230046; called by muse, mutect2, varscan2
- IRAG2 | c.3665G>A p.R1222K (on ENST00000636465; = p.R267K on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs367987808, COSV100611891; called by muse, mutect2, varscan2
- IRF6 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as COSV65420514; called by muse, mutect2, varscan2
- IRGC | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.871); catalogued as rs1041254422, COSV54986508; called by muse, mutect2, varscan2
- ITGA5 | c.1399G>A p.D467N | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53220954; called by muse, mutect2, varscan2
- ITGAX | c.3124G>A p.E1042K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.517); catalogued as COSV51647013; called by muse, mutect2, varscan2
- ITGB2 | c.1918C>T p.P640S (on ENST00000302347; = p.P616S on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.029); catalogued as COSV56614435; called by muse, mutect2, varscan2
- ITIH4 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 28/65 reads (43%) | catalogued as COSV56579287; called by muse, mutect2, varscan2
- ITPR1 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57005985; called by muse, mutect2, varscan2
- JAKMIP2 | c.2353C>T p.R785C | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs1381603155, COSV54616439; called by muse, mutect2, varscan2
- JAKMIP3 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53829990; called by muse, mutect2, varscan2
- JAML | c.550C>T p.R184C (on ENST00000356289 / NM_001098526.2; = p.R174C on NM_153206.3) | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs774147626, COSV52627117, COSV52627225; called by muse, mutect2, varscan2
- KCNAB1 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as rs1481068176, COSV67490794; called by muse, mutect2, varscan2
- KCNH3 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs745657618, COSV57793188; called by muse, mutect2, varscan2
- KCNH5 | c.2620C>T p.R874C | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs754436628, COSV59753363; called by muse, mutect2, varscan2
- KCNJ3 | c.96C>A p.D32E | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54545534; called by muse, mutect2, varscan2
- KCNJ5 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.724); catalogued as COSV57971615; called by muse, mutect2, varscan2
- KCNJ6 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55724043; called by muse, mutect2, varscan2
- KCNK10 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as rs867773131, COSV56649573; called by muse, mutect2, varscan2
- KCNMA1 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.091); catalogued as COSV54289993, COSV54291407; called by muse, mutect2, varscan2
- KCNQ2 | c.1871G>A p.G624E (on ENST00000359125 / NM_172107.4; = p.G596E on NM_004518.6) | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as COSV60555084; called by muse, mutect2, varscan2
- KCNT1 | c.483G>A p.Q161= (on ENST00000488444; = p.Q180= on NM_020822.3) | Splice Region (SNP) | VAF 21/48 reads (44%) | catalogued as rs1369301873, COSV53711975; called by muse, mutect2, varscan2
- KCNT1 | c.2546G>A p.S849N (on ENST00000488444; = p.S868N on NM_020822.3) | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV53712004; called by muse, mutect2, varscan2
- KCTD16 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV72577197; called by muse, mutect2, varscan2
- KCTD19 | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV58575558; called by muse, mutect2, varscan2
- KIAA1522 | c.2018C>T p.S673F (on ENST00000373480 / NM_001198972.2; = p.S732F on NM_020888.3) | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV53868204; called by muse, mutect2, varscan2
- KIF13A | c.2716C>T p.P906S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1335134210, COSV99438912; called by muse, mutect2, varscan2
- KIF14 | c.1955C>T p.P652L | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66260860; called by muse, mutect2, varscan2
- KIF2B | c.1360G>A p.G454R | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52131221; called by muse, mutect2, varscan2
- KIF6 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 102/173 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54696334; called by muse, mutect2, varscan2
- KIF6 | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54696365; called by muse, mutect2, varscan2
- KIF6 | c.164G>A p.S55N | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs1484992023, COSV54696387; called by muse, mutect2, varscan2
- KIF7 | c.1542G>C p.M514I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV67999632; called by muse, mutect2, varscan2
- KLC4 | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | catalogued as COSV52439499; called by muse, mutect2, varscan2
- KLHDC8A | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as rs746179707, COSV65679412; called by mutect2, varscan2
- KLK6 | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 23/60 reads (38%) | catalogued as COSV59566831; called by muse, mutect2, varscan2
- KLRC1 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as rs369792162, COSV61724885; called by muse, mutect2, varscan2
- KMT5B | c.2439G>A p.M813I | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.125); catalogued as COSV58569982; called by muse, mutect2, varscan2
- KNDC1 | c.2293G>A p.A765T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs1175376042, COSV58846988; called by muse, mutect2
- KRT17 | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV60862164; called by muse, mutect2, varscan2
- KRT222 | c.263A>C p.Q88P | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.583); catalogued as COSV67499312; called by muse, mutect2, varscan2
- KRT32 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV56786238; called by muse, mutect2, varscan2
- KRT35 | c.1273C>T p.P425S | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV55844719; called by muse, mutect2, varscan2
- KRT4 | c.999+1G>A p.X333_splice | Splice Site (SNP) | VAF 21/71 reads (30%) | catalogued as COSV99543303; called by muse, mutect2, varscan2
- KRT75 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1265293260, COSV52875437; called by muse, mutect2, varscan2
- KRT8 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.113); catalogued as rs1258310522, COSV53178254; called by muse, mutect2, varscan2
- KRT83 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.682); catalogued as COSV99532026; called by muse, mutect2, varscan2
- KRTAP10-6 | c.505T>C p.S169P | Missense Mutation (SNP) | VAF 78/153 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV59981765; called by muse, mutect2, varscan2
- KRTAP13-2 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.585); catalogued as COSV67762348; called by muse, mutect2, varscan2
- KRTAP15-1 | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV61878193; called by muse, mutect2, varscan2
- LAIR2 | c.69G>A p.E23= | Splice Region (SNP) | VAF 33/183 reads (18%) | catalogued as rs779830903, COSV56623157; called by muse, mutect2, varscan2
- LAMA1 | c.6491C>T p.S2164F | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as COSV101058066; called by mutect2, varscan2
- LAMA2 | c.1595G>A p.W532* | Nonsense Mutation (SNP) | VAF 10/17 reads (59%) | catalogued as COSV70356044; called by muse, mutect2, varscan2
- LAMA3 | c.9409C>T p.P3137S (on ENST00000313654 / NM_198129.4; = p.P1528S on NM_000227.6) | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.068); catalogued as COSV52544139; called by muse, mutect2, varscan2
- LAMB1 | c.3629G>A p.S1210N | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as rs369890673, COSV55970765; called by muse, mutect2, varscan2
- LAMB3 | c.3387G>A p.M1129I | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs1450188860, COSV50521997; called by muse, mutect2, varscan2
- LAMC3 | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as rs752093652, COSV63095671; called by muse, mutect2, varscan2
- LCE1D | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 35/133 reads (26%) | PolyPhen benign (0.044); catalogued as COSV58271859; called by muse, mutect2, varscan2
- LCE5A | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.192); catalogued as COSV57501692; called by muse, mutect2, varscan2
- LGMN | c.424T>C p.F142L | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58405401; called by muse, mutect2, varscan2
- LGR6 | c.896C>T p.S299L (on ENST00000367278 / NM_001017403.1; = p.S247L on NM_021636.3) | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs761470187, COSV55155712; called by muse, mutect2, varscan2
- LHX8 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as COSV53960447; called by muse, mutect2, varscan2
- LILRB1 | c.467G>A p.G156E (on ENST00000427581; = p.G120E on NM_006669.6) | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs763207069, COSV61120281; called by muse, mutect2, varscan2
- LIMCH1 | c.3182G>A p.R1061Q | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs754710831, COSV58274118; called by muse, mutect2, varscan2
- LIPE | c.23T>A p.V8E | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs1568617358, COSV54925878; called by muse, mutect2, varscan2
- LIPH | c.1014G>A p.W338* | Nonsense Mutation (SNP) | VAF 20/78 reads (26%) | catalogued as COSV56186605; called by muse, mutect2, varscan2
- LIPK | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs753196595, COSV68201987; called by muse, mutect2, varscan2
- LLPH | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs1162467321, COSV56982520; called by muse, mutect2, varscan2
- LOXL2 | c.376C>T p.L126F | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV66693838; called by muse, mutect2, varscan2
- LPA | c.5180G>A p.G1727E | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV60300607; called by muse, mutect2, varscan2
- LPAR1 | c.998A>T p.N333I | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.269); catalogued as COSV62691924; called by muse, mutect2, varscan2
- LRIT2 | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV60566869; called by muse, mutect2, varscan2
- LRP1B | c.13001C>T p.S4334L | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as COSV67191718; called by muse, mutect2, varscan2
- LRP1B | c.11140C>T p.L3714F | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.047); catalogued as rs1336711239, COSV67185170, COSV67189807; called by muse, mutect2, varscan2
- LRP1B | c.9834G>A p.M3278I | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV67205505; called by muse, mutect2, varscan2
- LRP1B | c.7295A>G p.N2432S | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as rs751161908, COSV67204348; called by muse, mutect2, varscan2
- LRP1B | c.4204C>T p.P1402S | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1480485544, COSV67197704, COSV67279355; called by muse, mutect2, varscan2
- LRP2 | c.497G>A p.W166* | Nonsense Mutation (SNP) | VAF 29/80 reads (36%) | catalogued as COSV55576799; called by muse, mutect2, varscan2
- LRRC47 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as COSV65563873; called by muse, mutect2, varscan2
- LRRC8C | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747378312, COSV64996016; called by muse, mutect2, varscan2
- LRRC8D | c.1657C>T p.P553S | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV61581461; called by muse, mutect2, varscan2
- LRRK2 | c.7132A>G p.K2378E | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV54172730; called by muse, mutect2, varscan2
- LRRN4CL | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as COSV54018005; called by muse, mutect2, varscan2
- LSP1 | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as rs142354742, COSV100288917; called by muse, varscan2
- LTBP1 | c.2153C>T p.P718L (on ENST00000404816 / NM_206943.4; = p.P392L on NM_000627.4) | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs868013289, COSV63186217; called by muse, mutect2, varscan2
- LVRN | c.1888C>T p.Q630* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as rs1000665710, COSV63498489; called by muse, mutect2, varscan2
- LY86 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs1185474608, COSV57913618; called by muse, mutect2, varscan2
- LYL1 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 74/179 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV53400084; called by muse, mutect2, varscan2
- MAFK | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.367); catalogued as rs1332156855, COSV52476053; called by muse, mutect2, varscan2
- MAG | c.1031C>T p.S344F | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62703205; called by muse, mutect2, varscan2
- MAGEA3 | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 46/68 reads (68%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs782712845, COSV100939011, COSV64756580; called by muse, mutect2, varscan2
- MAGEB4 | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.99); catalogued as COSV100974905, COSV66776727; called by muse, mutect2, varscan2
- MAIP1 | c.265C>T p.P89S | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV54461691; called by muse, mutect2, varscan2
- MAPK12 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.282); catalogued as rs1347956140, COSV53136103; called by muse, mutect2, varscan2
- MAPK9 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58126689; called by muse, mutect2, varscan2
- MAPT | c.1813C>T p.P605S (on ENST00000262410 / NM_001377265.1; = p.P213S on NM_005910.5) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV52243742; called by muse, mutect2, varscan2
- MARCO | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1254250452, COSV100503572, COSV59056535; called by muse, varscan2
- MATN4 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | PolyPhen possibly damaging (0.733); catalogued as COSV59216010; called by muse, mutect2, varscan2
- MCHR1 | c.540T>A p.F180L | Missense Mutation (SNP) | VAF 55/215 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV50763090; called by muse, mutect2, varscan2
- MCM2 | c.1372G>A p.D458N | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs376973485; called by muse, mutect2, varscan2
- MCM4 | c.1550C>T p.S517F | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50627958; called by muse, mutect2, varscan2
- MECOM | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); catalogued as COSV72111402; called by muse, mutect2, varscan2
- MED12L | c.3374C>T p.A1125V | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1472677463, COSV56399486; called by muse, mutect2, varscan2
- MET | c.404G>A p.S135N | Missense Mutation (SNP) | VAF 60/289 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1203410917, COSV59269460; called by muse, mutect2, varscan2
- METTL2A | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.883); catalogued as COSV61044256, COSV61046276; called by muse, mutect2, varscan2
- METTL2B | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.073); catalogued as COSV52308576, COSV52311316; called by muse, mutect2
- MFRP | c.79G>A p.A27T (on ENST00000449574; = p.A409T on NM_031433.4) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64129412; called by muse, mutect2, varscan2
- MFSD12 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs913056015, COSV62598630; called by muse, mutect2, varscan2
- MGAM | c.1990G>A p.D664N | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.046); catalogued as COSV72075980; called by muse, mutect2, varscan2
- MGAM | c.3272C>T p.P1091L | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72073904; called by muse, mutect2, varscan2
- MIA2 | c.938G>A p.G313E | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.209); catalogued as COSV54486848; called by muse, mutect2, varscan2
- MMP10 | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.24); PolyPhen probably damaging (1); catalogued as COSV54247974, COSV99666701; called by muse, mutect2, varscan2
- MMP19 | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 101/298 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV59453406; called by muse, mutect2, varscan2
- MMRN2 | c.85C>T p.L29F | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62318437; called by muse, mutect2, varscan2
- MOV10L1 | c.1295G>T p.C432F | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.038); catalogued as COSV53180406; called by muse, mutect2, varscan2
- MROH7 | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV59878537; called by muse, mutect2, varscan2
- MROH9 | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as rs1553213796, COSV63012646; called by muse, mutect2, varscan2
- MTCP1 | c.215A>C p.Y72S | Missense Mutation (SNP) | VAF 56/76 reads (74%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV62900776; called by muse, mutect2, varscan2
- MTHFD2L | c.514C>T p.H172Y (on ENST00000395759 / NM_001144978.2; = p.H114Y on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57470795; called by muse, mutect2, varscan2
- MTMR14 | c.1621G>C p.D541H | Missense Mutation (SNP) | VAF 82/234 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.819); catalogued as rs764076356, COSV56007911; called by muse, mutect2, varscan2
- MTOR | c.1652C>T p.P551L | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV63870813; called by muse, mutect2, varscan2
- MUC16 | c.40192C>T p.R13398C | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as rs764584308, COSV66690430; called by muse, mutect2, varscan2
- MUC16 | c.36087G>A p.W12029* | Nonsense Mutation (SNP) | VAF 5/11 reads (45%) | catalogued as COSV67496975; called by muse, mutect2, varscan2
- MUC16 | c.34483C>T p.P11495S | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.047); catalogued as COSV67451328; called by muse, mutect2, varscan2
- MUC16 | c.34279G>A p.G11427S | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.483); catalogued as COSV67496983; called by muse, mutect2, varscan2
- MUC16 | c.31105A>C p.S10369R | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.042); catalogued as COSV67496991; called by muse, mutect2, varscan2
- MUC16 | c.30082C>T p.P10028S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.156); catalogued as COSV67496995; called by muse, mutect2, varscan2
- MUC16 | c.27602C>A p.P9201Q | Missense Mutation (SNP) | VAF 60/145 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.269); catalogued as COSV67496999; called by muse, mutect2, varscan2
- MUC16 | c.23132C>T p.P7711L | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as COSV67469248; called by muse, mutect2, varscan2
- MUC16 | c.23131C>T p.P7711S | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.266); catalogued as rs578258727, COSV67455199; called by muse, mutect2, varscan2
- MUC16 | c.2815A>T p.I939L | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV67497012; called by muse, mutect2, varscan2
- MUC16 | c.1067C>T p.S356F | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as rs902031118, COSV67497015; called by muse, mutect2, varscan2
- MUC17 | c.7304G>T p.S2435I | Missense Mutation (SNP) | VAF 242/734 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as COSV60281608; called by muse, varscan2
- MUC17 | c.7307C>T p.S2436L | Missense Mutation (SNP) | VAF 233/729 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs776423510, COSV60305391; called by muse, varscan2
- MVK | c.337C>T p.L113F | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57333154; called by muse, mutect2, varscan2
- MYBL2 | c.1562C>T p.P521L | Missense Mutation (SNP) | VAF 96/297 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1251411613, COSV53834072, COSV99406927; called by muse, mutect2, varscan2
- MYBPC2 | c.2000G>A p.G667E | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63100313; called by muse, mutect2, varscan2
- MYF5 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.694); catalogued as COSV57355946; called by muse, mutect2, varscan2
- MYH15 | c.4891G>A p.E1631K | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV56320876; called by muse, mutect2, varscan2
- MYH2 | c.5563G>A p.E1855K | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55449676; called by muse, mutect2, varscan2
- MYH2 | c.4025C>T p.S1342F | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs267604721, COSV55431454; called by muse, mutect2, varscan2
- MYH4 | c.2335G>A p.E779K | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs776140827, COSV55116809; called by muse, mutect2, varscan2
- MYH7 | c.5191G>A p.D1731N | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs876657885, COSV62521523, COSV62524437; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO15A | c.6316G>T p.E2106* | Nonsense Mutation (SNP) | VAF 24/52 reads (46%) | catalogued as COSV52767214; called by muse, mutect2, varscan2
- MYO3A | c.4223A>G p.K1408R | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV56351304; called by muse, mutect2, varscan2
- MYO7B | c.2413A>G p.N805D | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV67352451; called by muse, mutect2, varscan2
- MYO9A | c.5392C>T p.P1798S | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV61858774; called by muse, mutect2, varscan2
- MYOCD | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV58513130; called by muse, mutect2, varscan2
- MYOCD | c.1270C>T p.P424S | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV58506770; called by muse, mutect2, varscan2
- MYOCD | c.1599G>A p.W533* | Nonsense Mutation (SNP) | VAF 24/54 reads (44%) | catalogued as COSV58499691; called by muse, mutect2, varscan2
- MYOT | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.747); catalogued as rs753957205, COSV53516298; called by muse, mutect2, varscan2
- MYOZ2 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.832); catalogued as COSV61086329; called by muse, mutect2, varscan2
- MYRIP | c.1810G>A p.D604N | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.29); catalogued as COSV56883224; called by muse, mutect2, varscan2
- MYT1L | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs757649588, COSV67717585; called by muse, mutect2, varscan2
- NAV2 | c.3221G>A p.R1074K (on ENST00000396087 / NM_001244963.2; = p.R1051K on NM_145117.5) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.986); catalogued as COSV60665961; called by muse, mutect2, varscan2
- NBEA | c.6701G>A p.R2234Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV59760527; called by muse, mutect2, varscan2
- NBEA | c.8738C>T p.S2913F | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV59826514; called by muse, mutect2, varscan2
- NBL1 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57031574; called by muse, mutect2, varscan2
- NCKAP5 | c.4622G>A p.G1541E | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1289081878, COSV58477854; called by muse, mutect2, varscan2
- NCKIPSD | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as COSV53663920; called by muse, mutect2, varscan2
- NCOA3 | c.1190C>T p.S397L | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as rs746732554, COSV59073933; called by muse, mutect2, varscan2
- NCOA6 | c.4469C>T p.S1490L | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1288559140, COSV62861530; called by muse, mutect2, varscan2
- NCOR2 | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs766316741, COSV62305242; called by muse, mutect2
- NDNF | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as COSV65634880; called by muse, mutect2, varscan2
- NDST4 | c.2341G>A p.E781K | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0.014); catalogued as COSV52137063; called by muse, mutect2, varscan2
- NEB | c.7186G>A p.D2396N | Missense Mutation (SNP) | VAF 90/256 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs867897450, COSV51078603; called by muse, mutect2, varscan2
- NEBL | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV65799610, COSV65800231; called by muse, mutect2, varscan2
- NEBL | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV65844627; called by muse, mutect2, varscan2
- NEDD9 | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.042); catalogued as COSV65223491; called by muse, mutect2, varscan2
- NETO1 | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 80/311 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55016017; called by muse, mutect2, varscan2
- NEXMIF | c.3590G>A p.R1197K | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT tolerated (0.32); PolyPhen benign (0.051); catalogued as COSV50044967, COSV50144828; called by muse, mutect2, varscan2
- NEXMIF | c.2329C>T p.H777Y | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT tolerated (0.12); PolyPhen benign (0.346); catalogued as COSV50145813; called by muse, mutect2, varscan2
- NEXN | c.555G>A p.M185I | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53944811; called by muse, mutect2, varscan2
- NFAT5 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63033341; called by muse, mutect2, varscan2
- NIBAN2 | c.696C>G p.N232K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV64825714; called by muse, mutect2, varscan2
- NIPAL1 | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 46/126 reads (37%) | catalogued as COSV55007824; called by muse, mutect2, varscan2
- NKAIN2 | c.379G>A p.A127T | Missense Mutation (SNP) | VAF 33/54 reads (61%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.998); catalogued as rs1430344867, COSV63690618; called by muse, mutect2, varscan2
- NLGN4X | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52038678; called by muse, mutect2, varscan2
- NLRP11 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64085449; called by muse, mutect2, varscan2
- NLRP11 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as rs868653172, COSV64088947; called by muse, mutect2, varscan2
- NLRP3 | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs201678213, COSV60227238; called by muse, mutect2, varscan2
- NLRP5 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.062); catalogued as rs755695459, COSV66767680; called by muse, mutect2, varscan2
- NLRP8 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs770625512, COSV52582790, COSV52587796; called by muse, mutect2, varscan2
- NOBOX | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 108/242 reads (45%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.041); catalogued as COSV56192875; called by muse, mutect2, varscan2
- NOS1 | c.1397T>C p.I466T | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs756175874, COSV57622663; called by muse, mutect2, varscan2
- NOS1 | c.592G>A p.G198S | Missense Mutation (SNP) | VAF 65/189 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.092); catalogued as COSV57622672; called by muse, mutect2, varscan2
- NOS2 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762375822, COSV100569758, COSV58227792; called by muse, mutect2, varscan2
- NOS3 | c.2056G>A p.D686N | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs755188330, COSV52491695, COSV52494767; called by muse, mutect2, varscan2
- NPAP1 | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV61511859; called by muse, mutect2, varscan2
- NPAP1 | c.1796C>T p.S599F | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs368007060; called by muse, mutect2, varscan2
- NPAS2 | c.1612C>T p.Q538* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV59562706; called by muse, mutect2, varscan2
- NPNT | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.217); catalogued as COSV59755793; called by muse, mutect2, varscan2
- NR2F2 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 75/234 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.389); catalogued as COSV67684208; called by muse, mutect2, varscan2
- NR3C2 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as COSV60984600, COSV61000554; called by muse, mutect2, varscan2
- NRG1 | c.1537C>T p.P513S (on ENST00000405005 / NM_013964.5; = p.P518S on NM_013956.5) | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55177470; called by muse, mutect2, varscan2
- NRK | c.4495G>A p.D1499N | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as rs181878602, COSV54607789; called by muse, mutect2, varscan2
- NT5C1B | c.997G>A p.E333K (on ENST00000359846 / NM_001199086.2; = p.E273K on NM_033253.4) | Missense Mutation (SNP) | VAF 64/196 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV58395597; called by muse, mutect2, varscan2
- NTN4 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59223921; called by muse, mutect2, varscan2
- NUTM2F | c.1715C>T p.S572F | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV53560696; called by muse, mutect2, varscan2
- NWD1 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as rs761500318, COSV60338980; called by muse, mutect2, varscan2
- NWD1 | c.1174C>T p.Q392* | Nonsense Mutation (SNP) | VAF 11/40 reads (28%) | catalogued as COSV60352561; called by muse, mutect2, varscan2
- NWD1 | c.3440C>T p.S1147F | Missense Mutation (SNP) | VAF 89/262 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs762233189, COSV60346297; called by muse, mutect2, varscan2
- NWD1 | c.4105G>A p.G1369R | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV60352600; called by muse, mutect2, varscan2
- NXPE3 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56292485; called by muse, mutect2, varscan2
- NXPH2 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV55647271; called by muse, mutect2, varscan2
- NYAP2 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs562957302, COSV56003370; called by muse, mutect2, varscan2
- OBI1 | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56147752; called by muse, mutect2, varscan2
- OFD1 | c.2830A>G p.N944D | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV57424986; called by muse, mutect2, varscan2
- OLFML2A | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.169); catalogued as COSV56585914; called by muse, mutect2, varscan2
- OPA1 | c.2372C>T p.S791F (on ENST00000361510 / NM_130837.3; = p.S736F on NM_015560.3) | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as COSV62483654; called by muse, mutect2, varscan2
- OR10AD1 | c.785A>G p.N262S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV59613193; called by muse, mutect2, varscan2
- OR10H5 | c.541G>A p.V181M | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.089); catalogued as rs776618344, COSV58277743, COSV58277919; called by muse, mutect2, varscan2
- OR10K2 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59222935; called by muse, mutect2, varscan2
- OR11G2 | c.629G>A p.R210K | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV62133221; called by muse, mutect2, varscan2
- OR11H6 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV59644265, COSV59645491; called by muse, mutect2, varscan2
- OR11L1 | c.486G>A p.M162I | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV63313995; called by muse, mutect2, varscan2
- OR13D1 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as COSV59513400; called by muse, mutect2, varscan2
- OR1F1 | c.697G>A p.G233R | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as COSV58962591; called by muse, mutect2, varscan2
- OR1N2 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 56/191 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs1328248049, COSV65461295; called by muse, mutect2, varscan2
- OR2A12 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV68822127; called by muse, mutect2, varscan2
- OR2A2 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 68/169 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as COSV68872628; called by muse, mutect2, varscan2
- OR2D2 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1190443433, COSV55058383; called by muse, mutect2, varscan2
- OR2L13 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV63562019; called by muse, mutect2, varscan2
- OR2W1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs1226192074, COSV65851432, COSV65851562, COSV65852021; called by muse, mutect2, varscan2
- OR4A5 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); catalogued as rs575024810, COSV60524478, COSV60524911; called by muse, varscan2
- OR4C15 | c.99C>G p.F33L | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV58951213, COSV58956039; called by muse, mutect2, varscan2
- OR4C15 | c.944C>T p.P315L (on ENST00000314644; = p.P261L on NM_001001920.2) | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.897); catalogued as COSV58951924, COSV58952417; called by muse, mutect2, varscan2
- OR4D5 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV58307045; called by muse, mutect2, varscan2
- OR4M1 | c.493C>T p.R165* | Nonsense Mutation (SNP) | VAF 50/250 reads (20%) | catalogued as rs550760273, COSV60061725; called by muse, mutect2, varscan2
- OR4N2 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 62/240 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as COSV60050752, COSV60054304; called by muse, mutect2, varscan2
- OR4N2 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100270120, COSV60055300; called by muse, mutect2, varscan2
- OR51F2 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV59066200; called by muse, mutect2, varscan2
- OR51G2 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58991807; called by muse, varscan2
- OR52I1 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 71/159 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs372649066; called by muse, mutect2, varscan2
- OR52J3 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66747109; called by muse, mutect2, varscan2
- OR52K2 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs761696597, COSV57835906; called by muse, mutect2, varscan2
- OR52M1 | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64172965; called by muse, mutect2, varscan2
- OR52R1 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs866371519, COSV61888830; called by muse, mutect2, varscan2
- OR5B12 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56906096, COSV56906902; called by muse, mutect2, varscan2
- OR5B3 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as COSV58676217; called by muse, varscan2
- OR5H2 | c.719G>A p.R240K | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.64); PolyPhen benign (0.06); catalogued as rs898480718, COSV62352008; called by muse, mutect2, varscan2
- OR5L2 | c.670A>C p.T224P | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV65725258; called by muse, mutect2, varscan2
- OR5P3 | c.105T>G p.Y35* | Nonsense Mutation (SNP) | VAF 20/89 reads (22%) | catalogued as COSV60429646, COSV60430061; called by muse, mutect2, varscan2
- OR5T1 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as rs868502201, COSV57301601; called by muse, mutect2, varscan2
- OR6C1 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV65573199; called by muse, mutect2, varscan2
- OR6C4 | c.164C>T p.T55I | Missense Mutation (SNP) | VAF 113/339 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.34); catalogued as rs758813099, COSV67793004, COSV67793342; called by muse, mutect2, varscan2
- OR6C4 | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.341); catalogued as COSV67792784; called by muse, mutect2, varscan2
- OR6F1 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV57466947; called by muse, mutect2, varscan2
- OR6S1 | c.449G>T p.C150F | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57839337; called by muse, mutect2
- OR6T1 | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1318997612, COSV58309733; called by muse, mutect2, varscan2
- OR7D2 | c.556C>T p.Q186* | Nonsense Mutation (SNP) | VAF 78/240 reads (33%) | catalogued as COSV60141547; called by muse, mutect2, varscan2
- OR8D1 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 72/206 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as rs1394295195, COSV63443141; called by muse, mutect2, varscan2
- OR8D2 | c.94C>T p.L32F | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs746287445, COSV62489137; called by muse, mutect2, varscan2
- OR8I2 | c.346G>A p.G116R | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV56170774; called by muse, mutect2, varscan2
- OR8U1 | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.217); catalogued as COSV56414979; called by muse, mutect2, varscan2
- OR9A2 | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63307174; called by muse, mutect2, varscan2
- OSMR | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 52/110 reads (47%) | catalogued as COSV57092679; called by muse, mutect2, varscan2
- OSMR | c.249G>A p.G83= | Splice Region (SNP) | VAF 34/79 reads (43%) | catalogued as rs1206371897, COSV57090560; called by muse, mutect2, varscan2
- OTOR | c.223G>T p.E75* | Nonsense Mutation (SNP) | VAF 13/52 reads (25%) | catalogued as rs745852897, CM138390, COSV55721651, COSV55723102; called by muse, mutect2, varscan2
- OTUD6A | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as COSV104405193, COSV57973472; called by muse, mutect2, varscan2
- OTUD7B | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64917512; called by muse, mutect2, varscan2
- OTULINL | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57036753; called by muse, varscan2
- P4HB | c.1301C>T p.A434V | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV58943039; called by muse, mutect2, varscan2
- PADI3 | c.1148G>A p.R383K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV100968624, COSV64934121; called by mutect2, varscan2
- PAPPA | c.2314C>T p.P772S | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.725); catalogued as COSV60277063; called by muse, mutect2, varscan2
- PAPPA | c.2480C>T p.S827F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs868292130, COSV60292745; called by muse, mutect2, varscan2
1,028 further variants in this file (446 protein-altering or splice-affecting, 528 silent, 54 other) are not listed here.
